Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RK-01A (Primary Tumor).

[page 1 of 2]
CSF ICD-O-3
Oligodendroglioma, grade II 945013
path
Oligoastrocytoma, grade II 938213
CSF
Site Brain, supratentorial NOS 271.0
path
Brain, frontal lobe 271.1
9414413

Nature of material: Brain
Received on:

Macroscopy:

Received in formalin, a portion of irregular brain that weighs 24.0 g and measures 4.5 X 3.5 X 2.0 cm. Is lined by smooth, delicate and translucent leptomeninges, under which it is possible to recognize two broad gyri. To cuts, there is loss of distinction between cortex and subcortical white matter due to irregular lesion, ill-defined, localized predominantly in the white matter, composed of brown tissue, something firm, with multiple small cavities, sometimes blackened, giving a spongy.

Microscopy:

Histological sections stained with H & E show infiltrative glial neoplasm, moderately cellular, affecting the cortex and white matter, and composed of a mixed population of glial cells. Most of these have round nuclei, dispersed chromatin and occasional perinuclear halos and is located in the middle of areas with loose fibrillar matrix, forming microcysts. Occasionally, we can observe some cells with eosinophilic and dense cytoplasm, with eccentric nuclei ("minigemistocysts"). Another type of cell is characterized by possessing more elongated nuclei with irregular outlines and dense chromatin arranged in a dense fibrillar matrix. It is not observed mitotic figures, microvascular proliferation or necrosis areas. It was performed immunohistochemistry that revealed strong positivity in neoplasia for anti-GFAP and focal positivity for S100 protein. A semi-quantitative assessment of proliferation index with MIB-1 antibody was positive in less than 1% of neoplastic nuclei.

Diagnosis:

Excision product of lesion on left frontal lobe: - Oligoastrocytoma, grade II - WHO classification 2007.

PROFESSIONAL PARTICIPANTS OF REPORT

Per TSS, dx discrepancy from
status TCGA turn to be
oligodendroglioma, grade II. BCL
w/ 8/13/13

H/PAA Discrepancy	☒	☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:

Study/Site: TCGA Brain lower grade glioma -

Brain Lower Grade Glioma)

Event: PathDiscrepancy

Interviewer:

Person ID: N/A

Age: N/A

Date of Birth:

Sex: M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Oligoastrocytoma grade II

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Oligodendroglioma grade II

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

wrote in TCGA Pathologic Diagnosis Discrepancy Form: "I did not participate in the initial diagnosis. When I reviewed the case, the astrocytic component is really doubtful".

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file bb4e1784-c65a-455e-b3ce-bf83bc807946 (TCGA-TQ-A7RK.740E07A6-7579-4967-827C-7DC0D56EFF98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).